Somatic mutation profile of tumor specimen ASCProject_0047_T1_WES (aliquot ASCProject_0047_T1_WES_1) from CMI case ASCProject_0047, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 68.3 years (24,959 days).
Specimen ASCProject_0047_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15b24066-9d34-4d73-b1ee-f70105dd2cef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0047_BLOOD_BC (Buffy Coat), aliquot ASCProject_0047_BLOOD_BC_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d88eee8-5a17-4d82-acd8-0bbf9e511311

The open-access MAF lists 264 somatic variants for this specimen: 169 protein-altering or splice-affecting, 76 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 76, Nonsense Mutation 7, Intron 6, RNA 4, 5'UTR 4, 3'UTR 3, Splice Region 2, 5'Flank 1, 3'Flank 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 17/158 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1064795070, COSV53025487, COSV53045576; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.2401C>T p.R801C (on ENST00000372530 / NM_001198934.2; = p.R773C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs371967874; called by muse, mutect2, varscan2
- ABCC9 | c.1271T>C p.L424P | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99687111; called by muse, mutect2
- ACHE | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs367977631; called by mutect2, varscan2
- ACKR3 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1325541874, COSV56020269; called by muse, mutect2, varscan2
- AL645922.1 | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs144339757; called by muse, mutect2
- ALOX12B | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs369807670; called by muse, mutect2, varscan2
- ANKS1B | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 15/432 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269579871, COSV61345301; called by muse, mutect2
- ARHGAP23 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs989878526; called by muse, mutect2, varscan2
- ARID2 | c.5360G>A p.R1787H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100536473; called by muse, mutect2
- ASTN1 | c.3334C>T p.R1112* | Nonsense Mutation (SNP) | VAF 30/258 reads (12%) | catalogued as rs199961480; called by muse, mutect2, varscan2
- ATG2A | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1244193296, COSV65967971; called by muse, mutect2, varscan2
- ATP8B3 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375279107; called by muse, mutect2, varscan2
- BLVRA | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 31/408 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1228733565; called by muse, mutect2
- BRPF3 | c.3598G>A p.V1200I | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1232553385, COSV60207873; called by muse, mutect2
- CACNA1A | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as rs1473069840; called by muse, mutect2
- CACNA2D1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1224350198, COSV62396491; called by muse, mutect2, varscan2
- CASP8 | c.1303C>T p.R435* (on ENST00000432109 / NM_033355.3; = p.R452* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 16/306 reads (5%) | catalogued as rs1368296717, COSV51844657; called by muse, mutect2
- CCDC14 | c.2675C>T p.A892V (on ENST00000488653; = p.A844V on NM_022757.5) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756018919, COSV59944301; called by muse, mutect2, varscan2
- CCDC88C | c.6010G>A p.V2004I | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs370102360, COSV57795777; called by muse, mutect2, varscan2
- CDH23 | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745855338, CM112923, COSV99822208; called by mutect2, varscan2
- CHRNA10 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99167129; called by muse, mutect2
- CLCN7 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs757590102, COSV51972920; called by muse, mutect2
- CLCNKB | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 24/582 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs1351882928, COSV65161621; called by muse, mutect2
- CNN1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs889642307; called by muse, mutect2
- CRAMP1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1008535036; called by muse, mutect2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2
- DKKL1 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55562185; called by muse, mutect2
- DUOX1 | c.3148G>A p.V1050M | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV58481445; called by muse, mutect2, varscan2
- EPB41L1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 68/787 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759662141, COSV52437690; called by muse, mutect2
- EPB41L2 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 35/460 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200008469, COSV61358160; called by muse, mutect2
- EPHA2 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626325, COSV64452197, COSV64452207; called by muse, mutect2
- ERBB2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745625627, COSV54087873; called by muse, mutect2, varscan2
- ESR2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs905821436, COSV50829088, COSV50829835; called by muse, mutect2
- ETNK2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1420802320, COSV99689654; called by muse, mutect2
- FAM13C | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 18/519 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1431276508, COSV53244064; called by muse, mutect2
- FAT3 | c.7048C>T p.R2350* | Nonsense Mutation (SNP) | VAF 16/187 reads (9%) | catalogued as rs1000769534; called by muse, mutect2
- FBXO10 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52833761; called by muse, mutect2
- FKBP1C | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.422); catalogued as rs1294799557, COSV100644686; called by muse, mutect2
- FLG | c.10117C>T p.R3373C | Missense Mutation (SNP) | VAF 50/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs574781406, COSV100912444; called by muse, mutect2
- GATA1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 27/507 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782632688, COSV64962877; called by muse, mutect2
- GLIS2 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333060955; called by muse, mutect2
- GPR179 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.55); catalogued as rs200034026; called by muse, mutect2, varscan2
- GPR26 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs755508152, COSV99500873; called by muse, mutect2, varscan2
- GPR4 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV100547104; called by muse, mutect2
- GPRIN3 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1041977298; called by muse, mutect2
- GPSM1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1278475751, COSV61304618; called by muse, mutect2
- HAO2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs201600052; called by muse, mutect2
- HRNR | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV64258717; called by muse, mutect2
- ICE1 | c.4003G>A p.G1335S | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99664999; called by muse, mutect2
- IGHD1-1 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 14/184 reads (8%) | PolyPhen benign (0.025); catalogued as rs368939942; called by muse, mutect2
- ISLR2 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV62302119; called by muse, mutect2
- ITCH | c.773G>A p.R258Q (on ENST00000262650 / NM_001257137.3; = p.R217Q on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); catalogued as rs1191416990; called by muse, mutect2
- JAKMIP1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.996); catalogued as COSV51528035; called by muse, mutect2
- KATNIP | c.4102C>T p.R1368W | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs766568487; called by muse, mutect2, varscan2
- KCNK13 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 23/295 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199088733, COSV56417166; called by muse, mutect2
- KCNK2 | c.766G>A p.A256T (on ENST00000444842 / NM_001017425.3; = p.A241T on NM_014217.4) | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs772497750, COSV67204248; called by muse, mutect2, varscan2
- KIAA1210 | c.2911G>A p.A971T | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.412); catalogued as rs1455497758; called by muse, mutect2
- KIF22 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 51/585 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765292943; called by muse, mutect2
- LAMC2 | c.1766G>A p.G589D | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99917214; called by muse, mutect2
- LLGL2 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs893540567, COSV51418322; called by muse, mutect2
- LOXL4 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.958); catalogued as rs1220310641; called by muse, mutect2
- LRCH4 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1462969296; called by muse, mutect2
- LRRTM4 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as rs878988220, COSV101297423, COSV69138902, COSV69140714; called by muse, mutect2, varscan2
- LZTR1 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs375451574; called by muse, mutect2, varscan2
- MAP1B | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs761941048, COSV57094091; called by muse, mutect2, varscan2
- MEGF11 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487956044; called by muse, mutect2, varscan2
- METTL25 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 14/101 reads (14%) | catalogued as rs372705146; called by muse, mutect2, varscan2
- MUC6 | c.3259C>T p.R1087C | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1265261633, COSV101424935, COSV70141299; called by muse, mutect2, varscan2
- MXI1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1272964809, COSV53292745; called by muse, mutect2, varscan2
- MYH11 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 30/547 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.414); catalogued as rs764831521, CM158366, COSV100259661; called by muse, mutect2
- MYH2 | c.2305-3C>T | Splice Region (SNP) | VAF 44/502 reads (9%) | catalogued as rs1317717541; called by muse, mutect2
- MYO15A | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); catalogued as rs1434562033; called by muse, mutect2, varscan2
- MYO15A | c.10081G>A p.V3361M | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs773647512, COSV52753433; called by muse, mutect2
- MYT1L | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as rs1024589526; called by muse, mutect2
- NCOR2 | c.7334G>A p.R2445H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs751919228; called by mutect2, varscan2
- NCR3LG1 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.127); catalogued as rs957248562; called by muse, mutect2
- NLGN3 | c.1882G>A p.V628M (on ENST00000358741 / NM_181303.2; = p.V608M on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/347 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs756381643, COSV62444499; called by muse, mutect2
- NR1H2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1568595480, COSV99516196; called by muse, mutect2
- OPLAH | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544934035, COSV70678695; called by muse, mutect2
- OR51B4 | c.781T>C p.F261L | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66517118; called by muse, mutect2
- PCDHA1 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 39/405 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV65374886; called by muse, mutect2, varscan2
- PHACTR3 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1332569140, COSV63025673; called by mutect2, varscan2
- PLEC | c.10627C>T p.R3543C (on ENST00000322810 / NM_201380.4; = p.R3433C on NM_000445.5) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.742); catalogued as rs781882032; ClinVar: uncertain significance; called by muse, mutect2
- PLG | c.2194T>C p.Y732H | Missense Mutation (SNP) | VAF 35/389 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.053); catalogued as rs145177652; called by muse, mutect2
- PLOD3 | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 49/475 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs531449765; called by muse, mutect2, varscan2
- POT1 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1554426994, COSV62932243; ClinVar: uncertain significance; called by muse, varscan2
- RAB27B | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340082952; called by muse, mutect2, varscan2
- SAGE1 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.826); catalogued as rs140797723; called by muse, mutect2
- SENP6 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64189689; called by muse, mutect2, varscan2
- SH3RF1 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as rs751242917, COSV52918788; called by muse, mutect2, varscan2
- SHANK3 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1196574155, COSV99438323; called by muse, mutect2
- SLC12A8 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 35/396 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs565606261; called by muse, mutect2
- SLC25A19 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 43/524 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.036); catalogued as rs758036010; called by muse, mutect2
- SLC2A1 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.206); catalogued as rs920394412; ClinVar: uncertain significance; called by muse, mutect2
- SLC39A6 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as rs1567957427, COSV99309324; called by muse, mutect2
- SLC3A1 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778587102; ClinVar: uncertain significance; called by muse, mutect2
- SLC6A17 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs142828529; called by muse, mutect2, varscan2
- SMC1A | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs781812690; called by muse, mutect2
- SPDYE3 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 47/525 reads (9%) | SIFT deleterious (0); catalogued as rs199979922; called by muse, mutect2, varscan2
- TARS1 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773111470, COSV54310848; called by mutect2, varscan2
- TBC1D4 | c.3796C>T p.R1266W | Missense Mutation (SNP) | VAF 38/528 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs367591642; called by muse, mutect2
- TERT | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1388678536, COSV57242106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TFDP1 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1311026964, COSV64740263; called by muse, mutect2
- TGM6 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 32/500 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202245813; ClinVar: uncertain significance; called by muse, mutect2
- TLN2 | c.4777G>A p.E1593K | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as rs1234700579, COSV100168478, COSV60891110; called by muse, mutect2
- TMC6 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs375980611; called by mutect2, varscan2
- TMEM132A | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs547896384; called by mutect2, varscan2
- TMEM151B | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs1001578906, COSV71285190; called by muse, mutect2
- TRIM29 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs1346186004, COSV100531940; called by muse, mutect2
- TRIOBP | c.4159C>T p.R1387W | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs370108541; called by muse, mutect2
- UNC80 | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 30/622 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs983037506, COSV55905874; called by muse, mutect2
- URB1 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs377601197; called by muse, mutect2
- VASN | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as rs1043106680; called by muse, mutect2
- VCL | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 26/524 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as rs992716111; ClinVar: uncertain significance; called by muse, mutect2
- VPS13D | c.12682C>T p.R4228W | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757964463; called by muse, varscan2
- WDR97 | c.3151G>A p.A1051T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs538418179; called by mutect2, varscan2
- XPNPEP1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 20/385 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1257325783; called by muse, mutect2
- XYLT2 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1186853460, COSV50020164; called by muse, mutect2, varscan2
- ZBTB3 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1235161007, COSV67360851; called by muse, mutect2
- ZNF761 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as rs1271014639; called by muse, mutect2
- ZSCAN20 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 23/457 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63684406; called by muse, mutect2
- ZSCAN4 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs141505405; called by muse, mutect2, varscan2
- ADGRB3 | c.2333G>A p.R778K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- ANO4 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.14); called by muse, mutect2
- ARHGAP36 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 36/605 reads (6%) | called by muse, mutect2
- BUB1B | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 20/315 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2
- CABP1 | c.1024C>T p.R342* (on ENST00000316803 / NM_001033677.1; = p.R139* on NM_004276.5) | Nonsense Mutation (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- CACNA1S | c.2651G>A p.G884E | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- COLGALT2 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.026); called by muse, mutect2
- DHX36 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2
- DIPK2B | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- EGFL6 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.045); called by muse, mutect2
- ERBB4 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.667); called by muse, mutect2
- EVC2 | c.3539C>T p.A1180V | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2
- FOXG1 | c.1253T>C p.F418S | Missense Mutation (SNP) | VAF 27/534 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); called by muse, mutect2
- GCLM | c.44C>G p.A15G | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2
- GTF2E1 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- ITSN1 | c.3727C>T p.H1243Y | Missense Mutation (SNP) | VAF 30/333 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2
- KIAA1109 | c.7288T>C p.F2430L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL22 | c.-32C>T | Splice Region (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- LAMA2 | c.6014C>T p.A2005V | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MMP1 | c.1028del p.F343Sfs*32 | Frame Shift Del (DEL) | VAF 12/124 reads (10%) | called by mutect2, pindel
- MMP17 | c.722A>T p.D241V | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MSN | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- MYB | c.1568T>C p.L523P | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- MYO18B | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 29/329 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NAA11 | c.88T>A p.Y30N | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OPN4 | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR1D5 | c.362A>T p.D121V | Missense Mutation (SNP) | VAF 48/738 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCYT2 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPEF2 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.545); called by muse, mutect2
- PPP2R5D | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 24/329 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- PRDM14 | c.1249A>G p.K417E | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMC2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2
- PTPRT | c.2743A>G p.K915E | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- REPS1 | c.2059G>A p.A687T (on ENST00000450536 / NM_001286611.2; = p.A686T on NM_031922.4) | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- RFX1 | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- RNF113A | c.350C>G p.T117R | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF17 | c.1443T>G p.C481W | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RSPRY1 | c.80T>G p.I27R | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- SLC9A7 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); called by muse, mutect2
- SPEG | c.4949C>T p.A1650V | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- STX16 | c.144+2T>C p.X48_splice | Splice Site (SNP) | VAF 16/237 reads (7%) | called by muse, mutect2
- TMIGD3 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 23/245 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- USP27X | c.356A>T p.E119V | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2
- ZNF445 | c.3005G>A p.R1002Q | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.821); called by muse, mutect2
- ZNF613 | c.1102G>T p.G368* (on ENST00000293471 / NM_001031721.4; = p.G332* on NM_024840.4) | Nonsense Mutation (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- ZNF705A | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ADCY7 | c.1359C>T p.I453= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs777729472; called by muse, mutect2, varscan2
- AGRN | c.903C>T p.R301= | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- ANKRD11 | c.525C>T p.A175= | Silent (SNP) | VAF 52/490 reads (11%) | catalogued as rs765896866, COSV56372795; called by muse, mutect2
- ANO5 | c.519A>T p.V173= | Silent (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- APBB2 | c.111C>T p.N37= | Silent (SNP) | VAF 22/463 reads (5%) | called by muse, mutect2
- ARX | c.1203G>A p.P401= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2
- ATP11A | c.2214C>T p.S738= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as rs775318504; called by muse, mutect2, varscan2
- BPIFB4 | c.774C>T p.N258= | Silent (SNP) | VAF 12/211 reads (6%) | catalogued as rs1488689709; called by muse, mutect2
- C19orf57 | c.1398C>T p.L466= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as rs1486798390; called by muse, mutect2, varscan2
- CD164L2 | c.45C>T p.G15= | Silent (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- CFAP20DC | c.1578C>T p.G526= (on ENST00000482387 / NM_001351530.2; = p.G401= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/205 reads (6%) | catalogued as rs1190394120; called by muse, mutect2
- CIC | c.4266G>A p.S1422= | Silent (SNP) | VAF 28/368 reads (8%) | catalogued as rs918119354; called by muse, mutect2
- CNTN3 | c.2010A>G p.E670= | Silent (SNP) | VAF 11/203 reads (5%) | catalogued as rs1424204333; called by muse, mutect2
- COG4 | c.2040C>T p.T680= | Silent (SNP) | VAF 58/673 reads (9%) | catalogued as rs143578462; called by muse, mutect2
- CUX1 | c.3957C>T p.S1319= | Silent (SNP) | VAF 10/212 reads (5%) | catalogued as rs1554537791; called by muse, mutect2
- CYP4B1 | c.735C>T p.R245= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as rs952710936; called by muse, mutect2
- DHX58 | c.1488C>T p.N496= | Silent (SNP) | VAF 30/273 reads (11%) | catalogued as rs373237712; called by muse, mutect2, varscan2
- DIDO1 | c.4581G>A p.S1527= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs1455215872, COSV56620511; called by muse, mutect2
- DNAH10 | c.9450C>T p.I3150= (on ENST00000409039; = p.I3089= on NM_207437.3) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs571743560, COSV68992062; called by muse, mutect2
- EPPK1 | c.3243C>T p.S1081= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs782522109; called by muse, mutect2
- FAM118A | c.423C>T p.G141= | Silent (SNP) | VAF 32/470 reads (7%) | catalogued as rs761248655, COSV53416290; called by muse, mutect2
- FAM83C | c.1089C>T p.L363= | Silent (SNP) | VAF 12/344 reads (3%) | catalogued as rs1027214353; called by muse, mutect2
- FREM3 | c.5628G>A p.T1876= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs968405393; called by muse, mutect2
- FRMPD1 | c.2169C>T p.S723= | Silent (SNP) | VAF 28/302 reads (9%) | catalogued as rs764877495; called by muse, mutect2
- GABRQ | c.1233G>A p.P411= | Silent (SNP) | VAF 19/275 reads (7%) | catalogued as rs782366909, COSV64783210; called by muse, mutect2
- GTF2H4 | c.141G>A p.E47= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as rs1397604225; called by muse, mutect2
- HDAC7 | c.756C>T p.P252= (on ENST00000427332; = p.P291= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as rs756567076; called by mutect2, varscan2
- HDAC9 | c.2967G>A p.P989= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as rs934474709, COSV67770591; called by muse, mutect2, varscan2
- HJURP | c.699C>T p.S233= | Silent (SNP) | VAF 27/411 reads (7%) | called by muse, mutect2
- IQGAP1 | c.693A>G p.R231= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- ITGB8 | c.1860C>T p.I620= | Silent (SNP) | VAF 46/483 reads (10%) | catalogued as rs374018734; called by muse, mutect2, varscan2
- JPH4 | c.1098C>T p.G366= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as COSV100689367; called by muse, mutect2, varscan2
- KIAA0930 | c.627C>T p.Y209= (on ENST00000336156 / NM_001009880.2; = p.Y214= on NM_015264.2) | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as rs759091591; called by muse, mutect2
- LGALS3BP | c.861C>T p.F287= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs138118783, COSV53164699; called by mutect2, varscan2
- LPO | c.1803C>T p.Y601= | Silent (SNP) | VAF 32/302 reads (11%) | catalogued as rs141238819, COSV99228493; called by muse, mutect2
- LRFN1 | c.804C>T p.R268= | Silent (SNP) | VAF 32/316 reads (10%) | catalogued as rs1022992628, COSV99952591; called by muse, mutect2, varscan2
- LRIT1 | c.1740C>T p.S580= | Silent (SNP) | VAF 32/251 reads (13%) | catalogued as rs201838718; called by muse, mutect2, varscan2
- LRRN4CL | c.456C>T p.C152= | Silent (SNP) | VAF 16/234 reads (7%) | catalogued as COSV54015417; called by muse, mutect2
- MAGEE1 | c.1185C>T p.T395= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as COSV63909132; called by muse, mutect2, varscan2
- MAP1A | c.2952C>T p.C984= | Silent (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2, varscan2
- MAP3K20 | c.1053C>T p.L351= | Silent (SNP) | VAF 13/267 reads (5%) | catalogued as rs1397802138, COSV64379336; called by muse, mutect2
- MCHR1 | c.1212C>T p.R404= | Silent (SNP) | VAF 23/197 reads (12%) | catalogued as rs201639451; called by muse, mutect2, varscan2
- MGAM2 | c.2946C>T p.A982= | Silent (SNP) | VAF 35/438 reads (8%) | catalogued as rs1049402579; called by muse, mutect2
- MROH2A | c.4047C>T p.A1349= | Silent (SNP) | VAF 17/200 reads (9%) | catalogued as rs985880440; called by muse, mutect2
- MYH14 | c.414C>T p.S138= | Silent (SNP) | VAF 26/368 reads (7%) | catalogued as rs746988346, COSV51810949; called by muse, mutect2
- PAX9 | c.324G>A p.A108= | Silent (SNP) | VAF 16/396 reads (4%) | called by muse, mutect2
- PCDH7 | c.778C>T p.L260= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- PCDHB15 | c.1554G>A p.S518= | Silent (SNP) | VAF 24/668 reads (4%) | called by muse, mutect2
- PNPLA6 | c.3384C>T p.D1128= (on ENST00000414982 / NM_001166111.2; = p.D1080= on NM_006702.5) | Silent (SNP) | VAF 46/562 reads (8%) | catalogued as rs765884981, COSV55383429; called by muse, mutect2
- PREP | c.1695G>A p.P565= (on ENST00000369110; = p.P631= on NM_002726.5) | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as rs764920544, COSV64869245; called by muse, mutect2
- PTPRD | c.2994G>A p.T998= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- RAB4B | c.540G>A p.P180= | Silent (SNP) | VAF 12/159 reads (8%) | called by muse, mutect2
- SATB1 | c.2013C>T p.D671= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as rs776065234, COSV58671216; called by muse, mutect2, varscan2
- SCARA5 | c.1284C>T p.D428= | Silent (SNP) | VAF 30/257 reads (12%) | catalogued as COSV61571958; called by muse, mutect2, varscan2
- SETDB1 | c.852A>T p.T284= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- SHC2 | c.975G>A p.S325= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs1397864019, COSV52743775; called by muse, mutect2, varscan2
- SHROOM2 | c.1743G>A p.P581= | Silent (SNP) | VAF 8/156 reads (5%) | catalogued as rs1425007128, COSV101098659; called by muse, mutect2
- SORBS2 | c.1155C>T p.D385= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as rs369888004; called by muse, mutect2, varscan2
- SPTBN2 | c.2064C>T p.G688= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs376219874; ClinVar: benign / uncertain significance; called by mutect2, varscan2
- STK11IP | c.1095A>G p.S365= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs753253372; called by muse, mutect2, varscan2
- TBC1D1 | c.567G>A p.P189= | Silent (SNP) | VAF 17/513 reads (3%) | catalogued as rs1223698264, COSV54728466; called by muse, mutect2
- TGM5 | c.177C>T p.F59= | Silent (SNP) | VAF 24/528 reads (5%) | called by muse, mutect2
- TMEM132D | c.483C>T p.A161= | Silent (SNP) | VAF 28/298 reads (9%) | catalogued as rs147829576; called by muse, mutect2
- TMEM151B | c.744G>A p.A248= | Silent (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- TOP3A | c.2880G>A p.S960= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as rs541672157, COSV58177313; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1146G>A p.P382= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as rs370011231; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP49 | c.1542C>T p.Y514= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as rs1467836837; called by muse, mutect2
- WDR1 | c.675C>T p.C225= (on ENST00000382452; = p.C85= on NM_005112.5) | Silent (SNP) | VAF 47/584 reads (8%) | catalogued as rs769928142; called by muse, mutect2
- ZBTB47 | c.1959G>A p.T653= | Silent (SNP) | VAF 13/290 reads (4%) | catalogued as rs1481657878; called by muse, mutect2
- ZNF385C | c.546C>T p.H182= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as rs984371378; called by muse, mutect2
- ZNF668 | c.102G>A p.A34= | Silent (SNP) | VAF 23/246 reads (9%) | catalogued as rs751555045; called by muse, mutect2
- ZNF716 | c.795A>G p.G265= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- ZNF74 | c.921C>T p.G307= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as rs1037455539, COSV62621269; called by muse, mutect2
- ZNRF4 | c.790C>T p.L264= | Silent (SNP) | VAF 12/276 reads (4%) | catalogued as COSV55774240; called by muse, mutect2
- ZP4 | c.213C>T p.S71= | Silent (SNP) | VAF 32/428 reads (7%) | catalogued as rs749178427, COSV100850717, COSV63911044, COSV63913060; called by muse, mutect2
- ZSWIM5 | c.1641C>T p.D547= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs749017745, COSV100655514; called by muse, mutect2, varscan2
- AC020907.6 | c.-392G>A | 5'UTR (SNP) | VAF 21/400 reads (5%) | catalogued as rs916585365; called by muse, mutect2
- ANKRD11 | c.87+3450C>T | Intron (SNP) | VAF 34/316 reads (11%) | catalogued as rs922465099; called by muse, mutect2
- ANO4 | c.-53G>A | 5'UTR (SNP) | VAF 38/440 reads (9%) | catalogued as rs531215302, COSV100151614; called by muse, mutect2
- CCDC116 | c.-49G>A | 5'UTR (SNP) | VAF 13/349 reads (4%) | called by muse, mutect2
- CT47B1 | c.*8A>G | 3'UTR (SNP) | VAF 19/367 reads (5%) | called by muse, mutect2
- DCHS2 | n.3954A>G | RNA (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- DCLRE1CP1 | n.101G>T | RNA (SNP) | VAF 34/434 reads (8%) | called by muse, mutect2
- GJD3 | c.*1944C>T | 3'UTR (SNP) | VAF 15/196 reads (8%) | catalogued as rs1012832063; called by muse, mutect2
- GRAMD2A | c.42-400G>A | Intron (SNP) | VAF 30/336 reads (9%) | catalogued as rs759645395; called by muse, mutect2
- HCAR2 | c.*10C>A | 3'UTR (SNP) | VAF 13/228 reads (6%) | catalogued as COSV61024603; called by muse, mutect2
- LIM2 | c.175+84T>A | Intron (SNP) | VAF 26/352 reads (7%) | called by muse, mutect2
- PRAME | c.22-1861G>A | Intron (SNP) | VAF 7/105 reads (7%) | catalogued as rs957640931; called by muse, mutect2
- SCARB2 | chr4:76214254 T>C | 5'Flank (SNP) | VAF 13/291 reads (4%) | called by muse, mutect2
- SSPOP | n.3702T>C | RNA (SNP) | VAF 9/76 reads (12%) | catalogued as rs1368009450; called by muse, mutect2, varscan2
- STEAP1 | chr7:90167906 C>T | 3'Flank (SNP) | VAF 11/177 reads (6%) | catalogued as rs1393329563; called by muse, mutect2
- TAZ | c.-105G>A | 5'UTR (SNP) | VAF 7/162 reads (4%) | called by muse, mutect2
- TFDP1 | c.1007-170G>A | Intron (SNP) | VAF 14/178 reads (8%) | catalogued as rs955441750; called by muse, mutect2
- WASF4P | n.1299C>T | RNA (SNP) | VAF 7/112 reads (6%) | catalogued as rs1556876040; called by muse, mutect2
- ZAN | c.7787+54G>A | Intron (SNP) | VAF 6/42 reads (14%) | catalogued as rs374344638, COSV61804786; called by mutect2, varscan2
